Surgical pathology report (de-identified scan), TCGA case TCGA-CG-4466, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-4466-01A (Primary Tumor).

■
Diagnosis:

Gastrectomy preparation with tumor-free resection margins and the inclusion of a subcardial moderately differentiated adenocarcinoma with infiltration of the lamina muscularis propria (■ pT2a L1 V0 R0) and distal to this a smaller, likewise moderately differentiated adenocarcinoma located approximately in the middle of the antrum with invasion of the submucosa (pT1 L0 V0 R0) (in each case gastric carcinoma of the intestinal type), in each case without regional lymph node metastases (pN0 0/13) evidently against the background of a multifocal atrophic previous pangastritis caused by *Helicobacter pylori*, with intestinal metaplasia.

Source: NCI Genomic Data Commons file dad7d9bd-5099-4f22-b97e-37891090d3f7 (TCGA-CG-4466.19FA8F4A-EB31-4235-8402-5964B8BAC610.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).